Somatic mutation profile of tumor specimen TCGA-13-1509-01A (aliquot TCGA-13-1509-01A-01W-0549-09) from TCGA case TCGA-13-1509, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.3 years (23,481 days).
Specimen TCGA-13-1509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c838f923-9cca-4aea-8226-a5ab239a7542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1509-10A (Blood Derived Normal), aliquot TCGA-13-1509-10A-01W-0550-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc3ebbdb-ff4f-4890-8921-5da0f2a2d25d

The open-access MAF lists 102 somatic variants for this specimen: 78 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 20, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 2, Intron 2, RNA 2, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, varscan2
- KIF26B | c.6071G>A p.R2024H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199933797, COSV63638897; called by muse, mutect2, varscan2
- AASDH | c.3236T>C p.I1079T | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs762824509, COSV52707071; called by muse, mutect2, varscan2
- ADAM2 | c.2175-2A>T p.X725_splice | Splice Site (SNP) | VAF 132/259 reads (51%) | catalogued as COSV55862974; called by muse, mutect2, varscan2
- ARHGAP21 | c.3186C>G p.N1062K | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.693); catalogued as COSV57606343; called by muse, mutect2, varscan2
- ARHGAP31 | c.2327A>C p.N776T | Missense Mutation (SNP) | VAF 135/559 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV51793731; called by muse, mutect2, varscan2
- AZI2 | c.217-1G>C p.X73_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | catalogued as COSV55424105; called by muse, mutect2, varscan2
- BRDT | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV62865298; called by muse, mutect2, varscan2
- CACNA1C | c.5294C>A p.A1765D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); catalogued as COSV59725118; called by muse, mutect2, varscan2
- CACNG1 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99871636; called by muse, mutect2, varscan2
- CD2AP | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs758166745, COSV63761024; called by muse, mutect2, varscan2
- CECR2 | c.2145dup p.L716Afs*6 (on ENST00000342247 / NM_001290047.2; = p.L533Afs*6 on NM_001290046.1) | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | catalogued as rs767205571; called by pindel, varscan2
- CENPE | c.7934T>C p.F2645S | Missense Mutation (SNP) | VAF 130/258 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV54382196; called by muse, mutect2, varscan2
- CMAS | c.960+2T>G p.X320_splice | Splice Site (SNP) | VAF 35/95 reads (37%) | catalogued as COSV57556684; called by muse, mutect2, varscan2
- CNTN4 | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61873990; called by muse, mutect2, varscan2
- CNTNAP2 | c.1171A>C p.N391H | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV62189039; called by muse, mutect2, varscan2
- CUBN | c.3760A>T p.S1254C | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64717177; called by muse, mutect2, varscan2
- CYP2B6 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 256/761 reads (34%) | catalogued as rs34097093, CM078372; ClinVar: drug response; called by muse, mutect2, varscan2
- DDX18 | c.1703T>C p.L568S | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54306909; called by muse, mutect2, varscan2
- DDX23 | c.1622G>T p.S541I | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV56398659; called by muse, mutect2, varscan2
- DMRT2 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV52402137; called by muse, mutect2, varscan2
- EIF4A2 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as COSV100125367; called by muse, mutect2, varscan2
- FAM186B | c.1324A>G p.K442E | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs564329811, COSV99218225; called by muse, mutect2
- FAT3 | c.6703T>G p.F2235V | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53118945; called by muse, mutect2, varscan2
- FCRL3 | c.620T>A p.M207K | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV63841983, COSV63844054; called by muse, mutect2, varscan2
- FLAD1 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV52697339; called by muse, mutect2, varscan2
- FMN2 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100143711; called by muse, mutect2, varscan2
- HK3 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 129/222 reads (58%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV52840709; called by muse, mutect2, varscan2
- HPS3 | c.2811A>C p.K937N | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV52831006; called by muse, mutect2, varscan2
- IFNB1 | c.333T>A p.N111K | Missense Mutation (SNP) | VAF 197/353 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1275860289, COSV66525459; called by muse, mutect2, varscan2
- IGSF10 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 15/459 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99177041; called by muse, mutect2
- IHO1 | c.831G>C p.L277F | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV99605918; called by muse, mutect2
- INPP4B | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 87/155 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53727814; called by muse, mutect2, varscan2
- LAMA2 | c.5212G>A p.E1738K | Missense Mutation (SNP) | VAF 201/454 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV70337092; called by muse, mutect2, varscan2
- LAMC1 | c.980C>G p.P327R | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51145600, COSV51173264; called by muse, mutect2, varscan2
- LMOD1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV66172842; called by muse, mutect2, varscan2
- LRCH3 | c.1049G>C p.R350T | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58392586; called by muse, mutect2, varscan2
- MAP3K2 | c.1391C>G p.T464S | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as COSV61294592; called by muse, mutect2, varscan2
- MAPKAP1 | c.1235A>G p.D412G (on ENST00000265960 / NM_001006617.3; = p.D376G on NM_024117.3) | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV56368688; called by muse, mutect2, varscan2
- MGST2 | c.412A>T p.N138Y | Missense Mutation (SNP) | VAF 85/142 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV55497850; called by muse, mutect2, varscan2
- MMS22L | c.2835G>C p.M945I | Missense Mutation (SNP) | VAF 133/244 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51521703; called by muse, mutect2, varscan2
- MOV10L1 | c.1708G>T p.V570F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53172750; called by muse, mutect2, varscan2
- NCF2 | c.501G>C p.W167C | Missense Mutation (SNP) | VAF 83/461 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as CD101803, COSV62315658, COSV62316073; called by muse, mutect2, varscan2
- NPHS1 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62288205; called by muse, mutect2, varscan2
- OPRK1 | c.1033T>C p.C345R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55571036; called by muse, mutect2, varscan2
- OR2F1 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67331489; called by muse, mutect2, varscan2
- OR51A4 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 108/295 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66749549; called by muse, mutect2, varscan2
- OS9 | c.1203G>T p.E401D | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99232418, COSV99232588; called by muse, mutect2, varscan2
- OS9 | c.1204A>T p.K402* | Nonsense Mutation (SNP) | VAF 26/118 reads (22%) | catalogued as COSV99232593; called by muse, mutect2, varscan2
- OTUB1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV99734823; called by muse, mutect2
- PHF21B | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs114160106; called by muse, mutect2, varscan2
- PIK3CG | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as COSV63249001; called by muse, mutect2, varscan2
- PKD1L1 | c.5903C>G p.A1968G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.466); catalogued as COSV56962499, COSV56966783; called by muse, mutect2, varscan2
- RADX | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV65318819; called by muse, mutect2, varscan2
- RB1 | c.2390_2406del p.L797* | Frame Shift Del (DEL) | VAF 55/120 reads (46%) | catalogued as COSV57309748; called by mutect2, pindel, varscan2
- RHBDD1 | c.785A>G p.D262G | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV58127356; called by muse, mutect2, varscan2
- RYR1 | c.9466G>A p.V3156I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as rs150230127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN10A | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs377467259; called by muse, mutect2, varscan2
- SCN2A | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51843205, COSV99332829; called by muse, mutect2, varscan2
- SLC26A8 | c.2890G>A p.G964S | Missense Mutation (SNP) | VAF 126/324 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV62886015, COSV62886045; called by muse, mutect2, varscan2
- SLC28A2 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV61664185; called by muse, mutect2, varscan2
- SLC37A3 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1223066954, COSV58262729, COSV58265444; called by muse, mutect2, varscan2
- SLC4A1 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV99293088; called by muse, mutect2, varscan2
- SLC4A4 | c.1289A>T p.H430L (on ENST00000264485 / NM_001098484.3; = p.H386L on NM_003759.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV52625667; called by muse, mutect2, varscan2
- SP110 | c.1777A>T p.K593* | Nonsense Mutation (SNP) | VAF 78/208 reads (38%) | catalogued as COSV51253040; called by muse, mutect2
- SPEF2 | c.3956C>T p.S1319L | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV61548779; called by muse, mutect2, varscan2
- SRPK1 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as COSV100644311, COSV60413153; called by muse, mutect2, varscan2
- ST6GAL2 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 73/148 reads (49%) | PolyPhen benign (0.196); catalogued as COSV62416894; called by muse, mutect2, varscan2
- STK32A | c.405C>G p.D135E | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100096761; called by muse, mutect2
- TP53 | c.988del p.L330Ffs*15 | Frame Shift Del (DEL) | VAF 73/170 reads (43%) | catalogued as COSV53825922, COSV99461761; called by mutect2, pindel, varscan2
- ZNF577 | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 125/305 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56816199; called by muse, mutect2, varscan2
- ZNF687 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.676); catalogued as COSV60679780; called by muse, mutect2, varscan2
- ZNF711 | c.1831T>C p.S611P | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52155197; called by muse, mutect2, varscan2
- DONSON | c.828_874del p.K276Nfs*10 | Frame Shift Del (DEL) | VAF 28/116 reads (24%) | called by mutect2, pindel
- FAM124B | c.475_480del p.I159_L160del | In Frame Del (DEL) | VAF 22/167 reads (13%) | called by mutect2, pindel, varscan2
- G2E3 | c.167_171del p.K56Rfs*18 | Frame Shift Del (DEL) | VAF 62/216 reads (29%) | called by mutect2, pindel, varscan2
- ODF2L | c.142_169del p.T48Rfs*4 | Frame Shift Del (DEL) | VAF 12/108 reads (11%) | called by mutect2, pindel
- SZRD1 | c.148_150delinsATTGTGATTC p.D50Ifs*87 | Frame Shift Ins (INS) | VAF 33/70 reads (47%) | called by pindel, varscan2*
- AGTPBP1 | c.3129A>T p.A1043= (on ENST00000357081 / NM_001330701.2; = p.A1003= on NM_015239.2) | Silent (SNP) | VAF 151/311 reads (49%) | catalogued as COSV61272313; called by muse, mutect2, varscan2
- ARL8A | c.342A>G p.L114= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV55343329; called by muse, mutect2, varscan2
- BSN | c.8028G>A p.T2676= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs763643890, COSV56519405; called by muse, mutect2, varscan2
- CDHR2 | c.27C>T p.F9= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1397044924; called by muse, mutect2
- CENPF | c.3898C>T p.L1300= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV65275435, COSV65279081; called by muse, mutect2, varscan2
- CP | c.309T>C p.D103= | Silent (SNP) | VAF 87/244 reads (36%) | catalogued as rs1285642820, COSV52831014; called by muse, mutect2, varscan2
- EML5 | c.804A>G p.P268= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1190865778, COSV61346415; called by muse, mutect2, varscan2
- GPR158 | c.3051T>C p.G1017= | Silent (SNP) | VAF 42/289 reads (15%) | catalogued as COSV66271515; called by muse, mutect2, varscan2
- KXD1 | c.483C>T p.A161= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as COSV99723624; called by muse, mutect2, varscan2
- LTBP4 | c.1734C>G p.L578= (on ENST00000308370 / NM_001042544.1; = p.L541= on NM_003573.2) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV52582504; called by muse, mutect2, varscan2
- MBD5 | c.3906A>C p.G1302= | Silent (SNP) | VAF 58/162 reads (36%) | catalogued as COSV68697299; called by muse, mutect2, varscan2
- MDM1 | c.204T>G p.S68= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as COSV57446465; called by muse, mutect2, varscan2
- PIGM | c.777T>C p.F259= | Silent (SNP) | VAF 182/561 reads (32%) | catalogued as COSV63635728; called by muse, mutect2, varscan2
- PRPF31 | c.837C>T p.I279= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs1374316824, COSV58085033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.4575A>T p.R1525= (on ENST00000303395 / NM_001202435.3; = p.R1514= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as COSV57672051; called by muse, mutect2, varscan2
- SLC4A1 | c.1218G>C p.L406= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV99293092; called by muse, mutect2, varscan2
- UBR2 | c.735T>C p.T245= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV65768824; called by muse, mutect2
- ZFAND3 | c.468G>T p.R156= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as COSV54726955; called by muse, mutect2, varscan2
- ZNF439 | c.903G>A p.K301= | Silent (SNP) | VAF 21/768 reads (3%) | called by muse, mutect2
- ZSCAN21 | c.963C>G p.T321= | Silent (SNP) | VAF 71/204 reads (35%) | catalogued as rs1562851156, COSV52850895; called by muse, mutect2, varscan2
- SNORD114-11 | n.68A>T | RNA (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- TTLL8 | c.938+375A>G | Intron (SNP) | VAF 31/53 reads (58%) | catalogued as rs1412666007, COSV56726015; called by muse, mutect2, varscan2
- TTN | c.10360+1346A>T | Intron (SNP) | VAF 125/362 reads (35%) | catalogued as COSV60103808; called by muse, mutect2, varscan2
- XIST | n.7273A>G | RNA (SNP) | VAF 8/79 reads (10%) | catalogued as rs1481511294; called by muse, varscan2
